Somatic mutation profile of tumor specimen MP2PRT-PATVHI-TBP1-A (aliquot MP2PRT-PATVHI-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATVHI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (581 days).
Specimen MP2PRT-PATVHI-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e780787-6bd8-461c-91d1-4bff7bb1b675.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVHI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVHI-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d7f780c-c971-4e18-8015-28a1f15d0a22

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 5'Flank 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 73/381 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GABRB3 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs773257229, COSV54671048, COSV54673017; called by muse, mutect2, varscan2
- JAK1 | c.2878C>T p.P960S | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61086746; called by muse, mutect2
- NUDT22 | c.849C>G p.N283K | Missense Mutation (SNP) | VAF 109/483 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as rs1323647367; called by muse, mutect2, varscan2
- RGS7BP | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 58/604 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1428877550, COSV61836266; called by muse, mutect2
- DNTT | c.419dup p.K141Efs*25 | Frame Shift Ins (INS) | VAF 114/388 reads (29%) | called by mutect2, pindel, varscan2
- GRM8 | c.2644A>G p.K882E | Missense Mutation (SNP) | VAF 129/360 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- IGKV3-20 | chr2:89142573 GAGGTGA>TTTTAG | Missense Mutation (DEL) | VAF 39/252 reads (15%) | called by pindel, varscan2*
- OLIG2 | c.502_504del p.E168del | In Frame Del (DEL) | VAF 92/634 reads (15%) | called by pindel, varscan2
- OR2A42 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by mutect2, varscan2
- NRG1 | chr8:31640040 G>A | 5'Flank (SNP) | VAF 50/310 reads (16%) | catalogued as rs890431354; called by muse, mutect2, varscan2
